Surgical pathology report (de-identified scan), TCGA case TCGA-06-0160, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0160-01A (Primary Tumor).

Patient Name

MRN:

Sex: Female Room/Bed:

PATH.NO:

NAME:

MED. REC. NO:

SURGERY DATE:

RECEIVE DATE:

PHYSICIAN:
COPY TO:-----
PATHOLOGICAL DIAGNOSIS:RIGHT FRONTAL LOBE BIOPSY: GLIOBLASTOMA MULTIFORME.
MIB-1: ABOUT 25%.

Operation/Specimen: Rt. frontal tumor.

Clinical History and Pre-Op Dx:

GROSS PATHOLOGY:

SPECIMEN: Right frontal tumor.
FIXATIVE: Formalin.
GENERAL: Multiple tissue fragments aggregating 1 x 1 by
0.5 cm.INTRAOPERATIVE CONSULTATION, Frozen section diagnosis: Glioma.
Submitted entirely in cassette 1 and 2.MICROSCOPIC: Sections show a high grade glioma with hypercellularity,
nuclear pleomorphism, mitotic figures, vascular hyperplasia, thrombosis
and large area of tumor necrosis.TISSUE COMMITTEE CODE:
BILLING CODES:

Source: NCI Genomic Data Commons file bea055ac-fdad-4c07-a371-15d8dccec4bc (TCGA-06-0160.F27602F4-41E9-45B2-85C2-68C01E90905D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).